Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9V3, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9V3-01A (Primary Tumor).

ICD O-3

Carcinoma, squamous cell
NOS 807043

Site: Cervix NOS C53.9

W 3/7/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1- "Biopsy of cervix":

Squamous cell carcinoma, invasive, grade III.
Angiolymphatic invasion absent.

Source: NCI Genomic Data Commons file a3aceb5d-650c-4668-af74-732cda35ef69 (TCGA-VS-A9V3.DCCE7881-D3D1-4DCF-875F-94E83F51D5E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).